Gene-level copy-number profile of tumor specimen TCGA-85-8277-01A from TCGA case TCGA-85-8277, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.6 years (25,793 days).
Specimen TCGA-85-8277-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0565ae29-1375-4653-937d-efff9a2c2b1f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8277-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0dfecb0a-6b0b-4dc9-8aeb-b0f471a8ee52

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,896; copy number 2: 25,290; copy number 3: 20,651; copy number 4: 9,722; copy number 5: 731; copy number 6: 874; copy number 7: 118; copy number 8: 268; copy number 9: 5; copy number 10: 69; copy number 11: 14; copy number 12: 59; copy number 13: 65; copy number 15: 18; copy number 24: 6; copy number 25: 2; copy number 35: 8; copy number 36: 1; copy number 40: 11; copy number 42: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8277-01A-11D-2292-01): tumor purity 0.56, ploidy 2.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr8:4,496,392–4,635,654, 2 genes: AC010941.1, AC022068.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,250 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,648,411–121,580,524, 49 genes, copy number 5–42 (within-gene range 1–42): PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr3:90,030,284–94,131,832, 16 genes, copy number 8: U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2.
- chr3:142,449,007–142,578,733, 1 gene, copy number 5 (within-gene range 4–5): ATR.
- chr3:142,580,910–155,183,704, 198 genes, copy number 5 (broad region; genes not listed).
- chr3:157,543,246–185,052,614, 414 genes, copy number 7–40 (within-gene range 4–40) (broad region; genes not listed).
- chr3:188,947,214–189,325,304, 1 gene, copy number 7 (within-gene range 3–7): TPRG1.
- chr3:189,238,686–198,222,513, 214 genes, copy number 5–7 (broad region; genes not listed).
- chr5:50,662,859–50,970,187, 8 genes, copy number 5: AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1.
- chr6:27,694,035–31,140,092, 249 genes, copy number 5–10 (within-gene range 1–10) (broad region; genes not listed).
- chr6:36,740,775–36,839,444, 1 gene, copy number 15 (within-gene range 3–15): CPNE5.
- chr6:36,841,430–37,394,734, 17 genes, copy number 15: Z85996.3, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P.
- chr6:38,565,950–38,588,529, 2 genes, copy number 25: Y_RNA, AL079341.1.
- chr7:82,589,848–97,181,763, 184 genes, copy number 5 (broad region; genes not listed).
- chr7:100,733,595–108,574,850, 181 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).
- chr9:35,360,540–36,830,456, 63 genes, copy number 7–12 (broad region; genes not listed).
- chr10:48,443,836–48,656,265, 4 genes, copy number 5 (within-gene range 4–5): AC016397.2, ARHGAP22, ARHGAP22-IT1, AC016397.1.
- chr11:41,714,534–41,875,997, 3 genes, copy number 5 (within-gene range 3–5): LINC01499, AC023442.1, AC023442.3.
- chr11:54,591,480–56,015,957, 63 genes, copy number 6 (broad region; genes not listed).
- chr11:68,312,591–74,398,433, 198 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr11:74,398,825–74,416,379, 2 genes, copy number 6: AP001085.1, MIR548AL.
- chr12:24,566,964–46,373,778, 331 genes, copy number 6–11 (broad region; genes not listed).
- chr12:46,384,233–46,407,166, 3 genes, copy number 6: AC025031.1, AC025031.4, AC025031.5.
- chr16:24,256,335–24,572,863, 5 genes, copy number 6 (within-gene range 2–6): CACNG3, AC004125.1, RNU7-24P, AC008938.1, RBBP6.
- chr16:24,661,422–24,671,062, 1 gene, copy number 6 (within-gene range 4–6): LINC01567.
- chr18:67,602,692–67,603,022, 1 gene, copy number 5: AC022662.1.
- chr19:29,489,775–30,085,893, 19 genes, copy number 5 (within-gene range 3–5): AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5.
- chr19:39,597,832–39,738,029, 13 genes, copy number 6: RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC.
- chr19:43,646,095–43,852,017, 9 genes, copy number 5 (within-gene range 1–5): PLAUR, RN7SL368P, AC005622.1, IRGC, SMG9, KCNN4, LYPD5, AC115522.1, ZNF283.

Autosomal genes at a single copy (total copy number 1): 1,895. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
